Somatic mutation profile of tumor specimen TCGA-24-1463-01A (aliquot TCGA-24-1463-01A-01W-0549-09) from TCGA case TCGA-24-1463, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.5 years (25,734 days).
Specimen TCGA-24-1463-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78d30934-42d8-4105-82ae-ab397b10e407.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1463-10A (Blood Derived Normal), aliquot TCGA-24-1463-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9710e5d-f8e1-4e71-a1f0-4848ec118ab5

The open-access MAF lists 78 somatic variants for this specimen: 64 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 11, Frame Shift Del 3, Nonsense Mutation 3, In Frame Del 2, 3'UTR 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.821T>A p.V274D | Missense Mutation (SNP) | VAF 84/115 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057520006, COSV52662012, COSV52709979, COSV52761348, COSV53124293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAMP | c.44dup p.L16Tfs*9 | Frame Shift Ins (INS) | VAF 16/139 reads (12%) | catalogued as rs751284215; called by mutect2, varscan2
- ADAMTS16 | c.820T>C p.C274R | Missense Mutation (SNP) | VAF 74/479 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56997754; called by muse, mutect2, varscan2
- ADCY9 | c.3930A>T p.R1310S | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); catalogued as COSV53578309; called by muse, mutect2, varscan2
- ANLN | c.2980G>C p.E994Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1437946662, COSV56077768; called by muse, mutect2, varscan2
- ASPM | c.6332G>A p.R2111K | Missense Mutation (SNP) | VAF 97/339 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.326); catalogued as COSV54133623; called by muse, mutect2, varscan2
- C12orf42 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as rs756683623, COSV59386556; called by muse, mutect2, varscan2
- C7orf26 | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV60419469; called by muse, mutect2, varscan2
- CAMK2G | c.343C>G p.H115D | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as COSV99989422; called by muse, mutect2, varscan2
- CCZ1B | c.282T>G p.N94K | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as COSV57438380; called by muse, mutect2, varscan2
- CRB1 | c.302G>C p.G101A | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66344561; called by muse, mutect2, varscan2
- CYP4A11 | c.1281C>A p.N427K | Missense Mutation (SNP) | VAF 373/885 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV60224466; called by muse, mutect2, varscan2
- DCHS1 | c.884A>C p.N295T | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100201457; called by muse, mutect2, varscan2
- DDX5 | c.1598G>C p.G533A | Missense Mutation (SNP) | VAF 98/494 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1555670771, COSV56750254; called by muse, mutect2, varscan2
- DIDO1 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 198/317 reads (62%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.494); catalogued as COSV56628310; called by muse, mutect2, varscan2
- DNAH3 | c.10504G>T p.E3502* | Nonsense Mutation (SNP) | VAF 131/178 reads (74%) | catalogued as COSV54535328; called by muse, mutect2, varscan2
- DPP10 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.223); catalogued as rs150929011, COSV59684506; called by muse, mutect2, varscan2
- EEF1G | c.10G>T p.G4W | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV53470976; called by muse, mutect2, varscan2
- EHD1 | c.727A>T p.I243F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100276833; called by muse, mutect2, varscan2
- EIF2AK2 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51797580; called by muse, mutect2, varscan2
- EPX | c.1933C>T p.R645* | Nonsense Mutation (SNP) | VAF 65/177 reads (37%) | catalogued as rs779601859, COSV56595245, COSV56597919; called by muse, mutect2, varscan2
- GIMAP1 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100211929; called by muse, mutect2, varscan2
- HHAT | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs771415014, COSV54803872; called by muse, mutect2, varscan2
- IFTAP | c.280T>G p.L94V | Missense Mutation (SNP) | VAF 60/88 reads (68%) | SIFT tolerated (0.6); PolyPhen benign (0.107); catalogued as COSV100530923; called by muse, mutect2, varscan2
- IPP | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100739374; called by muse, mutect2, varscan2
- ITGA10 | c.1960G>C p.V654L | Missense Mutation (SNP) | VAF 244/604 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.142); catalogued as COSV65198206; called by muse, mutect2, varscan2
- KCNJ8 | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53717376; called by muse, mutect2, varscan2
- KIAA0825 | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100265544, COSV56951985; called by muse, mutect2, varscan2
- KIF4B | c.2138G>T p.R713L | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70530379, COSV70531050; called by muse, mutect2, varscan2
- KLKB1 | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV52997396; called by muse, mutect2, varscan2
- LPIN3 | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV64719390; called by muse, mutect2, varscan2
- LRCH1 | c.730A>G p.K244E | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs371417993; called by muse, mutect2, varscan2
- LRFN2 | c.2363C>T p.T788M | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57823665; called by muse, mutect2, varscan2
- LYAR | c.20A>G p.N7S | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.612); catalogued as rs1560097360, COSV58643399; called by muse, mutect2, varscan2
- MAP10 | c.1534C>G p.P512A | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.263); catalogued as COSV69364266; called by muse, mutect2, varscan2
- MYO7A | c.3572G>T p.G1191V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68685727; called by muse, mutect2, varscan2
- NCAM2 | c.117C>A p.F39L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV53090410; called by muse, mutect2
- OR2J2 | c.918G>T p.L306F | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV101013273; called by muse, mutect2, varscan2
- OR2J2 | c.919G>T p.G307W | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101013276; called by muse, mutect2, varscan2
- P2RX1 | c.1175T>G p.L392R | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV50121576; called by muse, mutect2, varscan2
- PCDHB12 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53398838, COSV99507309; called by muse, mutect2, varscan2
- PCDHGA2 | c.71G>C p.W24S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.022); catalogued as COSV99530476, COSV99546985; called by muse, mutect2, varscan2
- PEX3 | c.522T>A p.D174E | Missense Mutation (SNP) | VAF 75/260 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.103); catalogued as COSV62569120; called by muse, mutect2, varscan2
- QDPR | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 52/69 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV55551154; called by muse, mutect2, varscan2
- RBM15 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV100873398; called by muse, varscan2
- RPGRIP1L | c.1369G>C p.D457H | Missense Mutation (SNP) | VAF 40/45 reads (89%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV50906824, COSV50910623; called by muse, mutect2, varscan2
- RYR2 | c.14717A>T p.E4906V | Missense Mutation (SNP) | VAF 191/454 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63698297; called by muse, mutect2, varscan2
- SCNN1B | c.1300G>A p.V434M | Missense Mutation (SNP) | VAF 61/83 reads (73%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as rs201330438; called by muse, mutect2, varscan2
- SPAST | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100188295; called by muse, mutect2
- SPECC1 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 200/274 reads (73%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV54962025; called by muse, mutect2, varscan2
- TAS2R9 | c.626C>A p.T209N | Missense Mutation (SNP) | VAF 101/131 reads (77%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.914); catalogued as COSV53689849, COSV99553777; called by muse, mutect2, varscan2
- TENM2 | c.5566C>G p.R1856G (on ENST00000518659 / NM_001122679.2; = p.R1617G on NM_001080428.3) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs779854073, COSV69125358, COSV69135872; called by muse, mutect2, varscan2
- TKTL1 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 93/123 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782041727, COSV54213843; called by muse, mutect2, varscan2
- TRABD2A | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as COSV59104448; called by muse, mutect2, varscan2
- TXLNB | c.1396A>T p.K466* | Nonsense Mutation (SNP) | VAF 81/215 reads (38%) | catalogued as COSV100624824; called by muse, mutect2, varscan2
- WDR43 | c.1627G>C p.D543H | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68019083; called by muse, mutect2, varscan2
- ZNF341 | c.1404G>C p.K468N (on ENST00000375200 / NM_001282935.1; = p.K461N on NM_032819.4) | Missense Mutation (SNP) | VAF 157/373 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61010042; called by muse, mutect2, varscan2
- ZNF606 | c.2080C>T p.H694Y | Missense Mutation (SNP) | VAF 161/222 reads (73%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.729); catalogued as COSV58706153, COSV58707030; called by muse, mutect2, varscan2
- AKNAD1 | c.1103_1105del p.S368del | In Frame Del (DEL) | VAF 126/379 reads (33%) | called by pindel, varscan2
- DAAM2 | c.520_531del p.H174_L177del | In Frame Del (DEL) | VAF 67/236 reads (28%) | called by mutect2, pindel, varscan2
- MRC1 | c.3790C>T p.L1264F | Missense Mutation (SNP) | VAF 454/1056 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- NF1 | c.254_272del p.I85Kfs*12 | Frame Shift Del (DEL) | VAF 31/60 reads (52%) | called by mutect2, pindel, varscan2
- RB1 | c.1659_1674del p.C553Wfs*53 | Frame Shift Del (DEL) | VAF 95/128 reads (74%) | called by mutect2, pindel, varscan2
- RYK | c.1681_1692delinsAT p.G561Mfs*14 (on ENST00000620660 / NM_001005861.2; = p.G558Mfs*14 on NM_002958.4) | Frame Shift Del (DEL) | VAF 58/128 reads (45%) | called by pindel, varscan2*
- ACACA | c.6636A>G p.L2212= | Silent (SNP) | VAF 76/108 reads (70%) | called by muse, mutect2, varscan2
- COL5A3 | c.5190G>A p.T1730= | Silent (SNP) | VAF 81/118 reads (69%) | catalogued as rs1206800800, COSV53407015; called by muse, mutect2, varscan2
- FYB1 | c.330G>A p.L110= | Silent (SNP) | VAF 110/264 reads (42%) | catalogued as COSV100684795; called by muse, mutect2, varscan2
- GET3 | c.753G>A p.E251= | Silent (SNP) | VAF 60/98 reads (61%) | catalogued as COSV100628131; called by muse, mutect2, varscan2
- PGM2L1 | c.1056C>T p.F352= | Silent (SNP) | VAF 47/179 reads (26%) | catalogued as rs748570875, COSV53348120; called by muse, mutect2, varscan2
- PPIAL4G | c.408G>A p.V136= | Silent (SNP) | VAF 115/341 reads (34%) | catalogued as COSV70087298; called by muse, mutect2, varscan2
- RAB3GAP1 | c.2889C>T p.L963= | Silent (SNP) | VAF 60/129 reads (47%) | catalogued as COSV51478555; called by muse, mutect2, varscan2
- TPRKB | c.90A>G p.R30= | Silent (SNP) | VAF 77/228 reads (34%) | catalogued as COSV55541557; called by muse, mutect2, varscan2
- TTN | c.97599C>G p.V32533= (on ENST00000591111; = p.V25109= on NM_003319.4) | Silent (SNP) | VAF 111/313 reads (35%) | catalogued as COSV100592274, COSV60189082; called by muse, mutect2, varscan2
- ZNF862 | c.738G>T p.G246= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV56224908; called by muse, varscan2
- ZNRF3 | c.1125C>G p.T375= (on ENST00000544604 / NM_001206998.2; = p.T275= on NM_032173.3) | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV60436391; called by muse, mutect2, varscan2
- ATP2B2 | c.*153G>T | 3'UTR (SNP) | VAF 59/80 reads (74%) | catalogued as COSV59488068, COSV59502274; called by muse, mutect2, varscan2
- OR2U1P | n.329G>T | RNA (SNP) | VAF 171/413 reads (41%) | called by muse, mutect2, varscan2
- TRIM8 | c.*750G>C | 3'UTR (SNP) | VAF 16/37 reads (43%) | catalogued as COSV56661295; called by muse, varscan2
